HCMI case HCM-STAN-1109-D13 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/af78a845-bdb6-4245-b3a2-c94dbbf18653

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Days to birth: -15,620 days (42.8 years before the index date); Year of birth: 1973; Vital status: Alive.

Diagnoses (1)
1. Tubulovillous adenoma, NOS: ICD-O-3 morphology code: 8263/0; ICD-10 code: D13.2; Tissue or organ of origin: Small intestine, NOS; Site of resection or biopsy: Duodenum; Classification of tumor: Premalignant; AJCC staging edition: 8th; AJCC pathologic T: T0; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage 0; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Necrosis present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 2,343 days (6.4 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 2,029.

Molecular and laboratory tests
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 104 kg; Height: 173 cm; BMI: 34.7.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-STAN-1109-D13-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample HCM-STAN-1109-D13-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample HCM-STAN-1109-D13-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
